Surgical pathology report (de-identified scan), TCGA case TCGA-G9-6363, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-6363-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

- A. RIGHT PELVIC LYMPH NODES
- B. LEFT PELVIC LYMPH NODES
- C. PROSTATE
- D. LEFT APICAL MARGIN

TCGA - G9 - 6363

SPECIMEN(S):

- A. RIGHT PELVIC LYMPH NODES
- B. LEFT PELVIC LYMPH NODES
- C. PROSTATE
- D. LEFT APICAL MARGIN

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA/FSB-right and left pelvic lymph nodes: Negative for malignancy called by Dr. to Dr. at (A) and (B)

GROSS DESCRIPTION:

A. RIGHT PELVIC LYMPH NODES

Received fresh is a piece of adipose tissue, 6 x 3 x 2 cm, containing 3 lymph nodes. The largest measuring 5.1 x 1.1 x 0.8 cm and two smaller nodes, each 1 cm in greatest dimension. Lymph nodes are submitted entirely for frozen section diagnosis is follows:

FSA1: two smaller nodes

FSA2-FSA4: largest node

B. LEFT PELVIC LYMPH NODES

Received fresh are multiple pieces of adipose tissue, 6 x 3 x 2 cm in aggregate. Five possible lymph nodes are identified, 0.7 to 1.1 cm in greatest dimension. Lymph nodes are submitted entirely for frozen section diagnosis.

FSB1: 4 possible lymph nodes

FSB2: 1 lymph node

C. PROSTATE

Received fresh labeled with the patient's identification and designated "prostate" is a resected prostate gland weighing 80 g and measuring 6-cm from right to left, 5-cm from anterior to posterior, and 4.2-cm from apex to base. The capsule is smooth and intact. Ink code: Apex-red, anterior-orange, base-blue, posterior-black, right-green, left-yellow. The apex and base are removed from the specimen yielding a new weight of 29 g. The specimen is serially sectioned from apex to base showing firm tan bulging parenchyma. The right and left seminal vesicles, 2.5 x 2.7 x 1.5 cm, and 2.5 x 2.8 x 1.6 cm, respectively, are bisected to show beige tan cystic tissue. The right and left vas, 3 x 0.5 cm, and 4.1 x 0.5 cm, respectively, are serially sectioned to show firm tan tube structure. A portion of the specimen is submitted for tissue procurement, the remainder of the mid-portion is entirely submitted (with the exception of seminal vesicles and vas deferens):

C1-C3: Right apex

C4-C5: Left Apex

C6: Level 1 right side

C7: Level 1 left side

C8-C11: Level 2, capsule, right side

C12-C13: Level 2, capsule, left side

C14-C15: Right lateral base

C16-C19: Right base

C20-C21: Right base with distal urethral margin /bladder neck

C22-C23: Left base with distal urethral margin /bladder neck

C24-C29: Left base

C30-C32: Left lateral base

C33: Right seminal vesicle, right vas

C34: Left seminal vesicle, left vas

D. LEFT APICAL MARGIN

Received in formalin labeled with the patient's identification and designated "left apical margin" is an irregular fragment of brown-tan soft tissue measuring 0.7 x 0.5 x 0.3 cm. The entire specimen is submitted, D1.

[page 2 of 2]
DIAGNOSIS:

A. LYMPH NODES, RIGHT PELVIC, EXCISION:

- NO MALIGNANCY IDENTIFIED IN THREE LYMPH NODES (0/3).

B. LYMPH NODES, LEFT PELVIC, EXCISION:

- NO MALIGNANCY IDENTIFIED IN THREE LYMPH NODES (0/3).

C. PROSTATE, PROSTATECTOMY:

- ADENOCARCINOMA, CONVENTIONAL TYPE.
- GLEASON'S GRADE 4+3 = 7/10.
- COMPRISING APPROXIMATELY 20% OF THE GLAND.
- MULTIFOCAL, INVOLVING BOTH RIGHT AND LEFT LOBES.
- INVADING INTO THE BLADDER NECK.
- EXTRAPROSTATIC EXTENSION IS PRESENT IN THE BASE.
- NO SEMINAL VESICLE INVASION IDENTIFIED.
- ALL MARGINS ARE NEGATIVE FOR TUMOR.
- ANGIOLYMPHATIC INVASION IS PRESENT IN THE RIGHT BASE.
- EXTENSIVE PERINEURAL INVASION IS PRESENT IN THE RIGHT AND LEFT LOBES.
- HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA.

D. PROSTATE, LEFT APICAL MARGIN, EXCISION:

- NO MALIGNANCY IDENTIFIED.

SYNOPTIC REPORT - PROSTATE GLAND

Specimens Involved

Specimens: C: PROSTATE

Location: Left

Right

Posterior lateral

Apical

Basal

WHO CLASSIFICATION

Epithelial tumors

Adenocarcinoma 8140/3

Multicentricity: Yes

Gland Involvement: 20%

Gleason Grade/Sum:: Grade 4 + 3 , Sum 7

High Grade PIN Present: Yes

Perineural Invasion: Yes

Vascular/Lymphatic Invasion: Yes

Seminal Vesicle Invasion: No

Periprostatic Fat Involved: Yes

Details: base

Bladder Neck Involved: Yes

Margins Involvement: No

Frozen Performed: No

Lymph Nodes: Negative Right 0 / 3 Left 0 / 3

Other Pathologic Findings: None identified

Pathological Staging (pTNM): T 4 N 0 M X

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Prostate cancer

Source: NCI Genomic Data Commons file b52b8448-10b4-4b71-bf3e-3f2acf2dbcbf (TCGA-G9-6363.BD52CCC2-462D-41DF-A5A4-DC45BD78AEA4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).